Somatic mutation profile of tumor specimen TCGA-BS-A0UF-01A (aliquot TCGA-BS-A0UF-01A-11D-A10B-09) from TCGA case TCGA-BS-A0UF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.1 years (23,771 days).
Specimen TCGA-BS-A0UF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3638355-5cd5-495a-9de8-0a0fd1a5b7c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UF-10A (Blood Derived Normal), aliquot TCGA-BS-A0UF-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8820a0b4-f15b-47b2-9ef5-a4f9317a4360

The open-access MAF lists 9,395 somatic variants for this specimen: 7,630 protein-altering or splice-affecting, 1,586 silent, 179 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,361, Silent 1,586, Nonsense Mutation 1,054, Splice Site 103, Intron 83, RNA 58, Splice Region 43, Frame Shift Del 36, Frame Shift Ins 17, 3'UTR 11, 5'UTR 10, 5'Flank 10.

Variants (750 of 9,395; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs376926391, CM082466, CM122251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALB | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as rs77238412, CM870083, CM940020; ClinVar: pathogenic; called by mutect2, varscan2
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as rs199422141, CM091956, COSV54124524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs1363726955, COSV53725456; ClinVar: pathogenic; called by muse, varscan2
- ATP8B1 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as rs515726137, CM043824, COSV52172870, COSV52176779; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCS1L | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs386833857, CM022765, COSV55305887; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.5333-1G>T p.X1778_splice | Splice Site (SNP) | VAF 18/78 reads (23%) | catalogued as rs80358126, CS0910594, CS107814, CS1211726, COSV58783837; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.3191C>A p.S1064* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs864622609, COSV66448023; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CASR | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs1085307984, CM107259, COSV56134117; ClinVar: pathogenic; called by muse, varscan2
- CHEK2 | c.1090G>T p.E364* (on ENST00000382580 / NM_001005735.2; = p.E321* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as rs1555915433, CM062510, COSV60415453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs104886117, CM960361, COSV60355935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 62/174 reads (36%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as rs755995375, COSV61576496; called by muse, mutect2, varscan2
- DNMT3A | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs757823678, COSV53037113, COSV53081931; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DSG2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs371146201; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- F8 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs28937282, CM123898, CM930220, COSV100811418, COSV64269644, COSV64275734; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNC | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 58/197 reads (29%) | catalogued as rs755583250, COSV57950044; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLI1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381253752, COSV57357760; called by muse, mutect2, varscan2
- GNS | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs119461974, CM030467, COSV50697172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518621, COSV65565954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16391C>T p.T5464M | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607238, CM105488, COSV56409798; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MANBA | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | catalogued as rs121434335, CM024127, COSV56963551, COSV99898471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 58/190 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4588C>T p.R1530* | Nonsense Mutation (SNP) | VAF 42/122 reads (34%) | catalogued as rs397516225, COSV62516192; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NDUFS1 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs750971390, COSV51907881, COSV99260518; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.5567G>T p.R1856I | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554025796, CM042518, COSV56942001; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NLRP3 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121908153, CM021071, CM076355, COSV60219065; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PCDH19 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as rs769967221, CM1211675, COSV55257472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 55/162 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRLR | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as rs376188691, COSV51492949; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 41/138 reads (30%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- TCF4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs878853149, CM120282, COSV61890253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886038794, COSV55443484, COSV55454844; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THPO | c.532C>T p.R178C (on ENST00000649095 / NM_001290003.1; = p.R38C on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760797899, CM1312033, COSV52605324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMCO1 | c.412C>T p.R138* (on ENST00000612311 / NM_001256164.1; = p.R87* on NM_019026.6) | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as rs201213306, CM139137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 72/259 reads (28%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.88858C>T p.R29620* (on ENST00000591111; = p.R22196* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as rs1553528016, COSV59881459; ClinVar: likely pathogenic; called by muse, varscan2
- TTN | c.71981dup p.N23994Kfs*5 (on ENST00000591111; = p.N16570Kfs*5 on NM_003319.4) | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | catalogued as rs1553601017; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TTN | c.50877G>A p.W16959* (on ENST00000591111; = p.W9535* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs727503598, COSV59882086, COSV60406603; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1057517858, CM103939, COSV55496874, COSV55497525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.13576C>T p.R4526* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs1003869920, CM115977, COSV56326318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs764797292, CM001374, COSV56326392; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS53 | c.1516C>T p.R506* (on ENST00000571805 / NM_001366253.2; = p.R477* on NM_018289.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as rs200594402, CM164762, COSV52126085; ClinVar: likely pathogenic; called by muse, mutect2
- WAC | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as rs1564421528, COSV61566638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WNT2B | c.205C>T p.R69* (on ENST00000369684 / NM_024494.3; = p.R50* on NM_004185.4) | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs370244148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV59382720; called by muse, varscan2
- A2ML1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55285440; called by muse, mutect2, varscan2
- A2ML1 | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs762232957, COSV55285465; called by muse, mutect2, varscan2
- AAAS | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV52932192; called by muse, mutect2, varscan2
- AACS | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs376023356; called by muse, mutect2, varscan2
- AADAC | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1323878259, COSV51758177; called by muse, mutect2, varscan2
- AADACL2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs370936803; called by muse, mutect2, varscan2
- AAK1 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV68641709; called by muse, mutect2, varscan2
- AASDH | c.3232C>T p.L1078F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99220953; called by muse, mutect2, varscan2
- AASDH | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52703915, COSV52707743; called by muse, mutect2, varscan2
- ABAT | c.1363T>G p.L455V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1555493999, COSV51620131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.5948A>C p.E1983A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.038); catalogued as COSV66063666; called by muse, mutect2, varscan2
- ABCA1 | c.1703A>C p.K568T | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV66063672; called by muse, mutect2, varscan2
- ABCA1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458927804, COSV66057473, COSV66058563; called by muse, mutect2, varscan2
- ABCA10 | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52218066; called by muse, mutect2, varscan2
- ABCA10 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52218077; called by muse, mutect2, varscan2
- ABCA10 | c.1601G>T p.R534I | Missense Mutation (SNP) | VAF 95/359 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52218086; called by muse, mutect2, varscan2
- ABCA10 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV52218094; called by muse, mutect2, varscan2
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, mutect2, varscan2
- ABCA13 | c.3377A>G p.Q1126R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV70025731; called by muse, mutect2, varscan2
- ABCA13 | c.3378A>C p.Q1126H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV70025734; called by muse, mutect2, varscan2
- ABCA13 | c.4118G>A p.R1373H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201391209, COSV70025736; called by muse, mutect2, varscan2
- ABCA13 | c.5099G>A p.G1700E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV70025787; called by muse, mutect2, varscan2
- ABCA13 | c.6519A>T p.K2173N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV70025791; called by muse, mutect2, varscan2
- ABCA13 | c.6784G>T p.D2262Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV70032492; called by muse, mutect2
- ABCA13 | c.7428G>T p.K2476N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV71283225; called by muse, mutect2, varscan2
- ABCA13 | c.8465G>T p.R2822I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV71283228; called by muse, mutect2, varscan2
- ABCA13 | c.9775G>A p.D3259N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774039645, COSV71283232; called by muse, mutect2, varscan2
- ABCA13 | c.13090C>A p.P4364T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV101291232, COSV68950536; called by muse, mutect2, varscan2
- ABCA13 | c.14539G>A p.E4847K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs267601532, COSV68943207; called by muse, mutect2, varscan2
- ABCA13 | c.14998G>A p.A5000T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101291234, COSV101291423; called by muse, varscan2
- ABCA4 | c.6136G>T p.E2046* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV64670928; called by muse, mutect2, varscan2
- ABCA5 | c.3403G>T p.E1135* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV67015692; called by mutect2, varscan2
- ABCA5 | c.1842A>T p.K614N | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.096); catalogued as COSV67015698; called by muse, varscan2
- ABCA6 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as COSV52635421; called by muse, mutect2, varscan2
- ABCA6 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1476951371, COSV99446046; called by muse, mutect2, varscan2
- ABCA6 | c.358A>C p.N120H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV99446052; called by muse, varscan2
- ABCA7 | c.6300C>A p.F2100L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV54023985; called by muse, mutect2, varscan2
- ABCA8 | c.2541T>G p.Y847* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV52193980; called by muse, mutect2, varscan2
- ABCA8 | c.2060C>A p.S687* | Nonsense Mutation (SNP) | VAF 55/180 reads (31%) | catalogued as COSV52193998; called by muse, mutect2, varscan2
- ABCA8 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV52194015; called by muse, varscan2
- ABCA8 | c.1043C>A p.S348* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV52194036; called by muse, varscan2
- ABCA9 | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374873743; called by muse, mutect2, varscan2
- ABCA9 | c.3722C>A p.S1241Y | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV60620133; called by muse, mutect2, varscan2
- ABCA9 | c.2608C>A p.L870I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as COSV100382800; called by muse, varscan2
- ABCA9 | c.2455C>A p.L819I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV60620142; called by muse, mutect2, varscan2
- ABCA9 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756210320, COSV60620151; called by muse, mutect2, varscan2
- ABCB1 | c.2374G>A p.V792I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1216670269, COSV55944914; called by muse, mutect2, varscan2
- ABCB1 | c.1991G>T p.R664I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV55944923; called by muse, mutect2, varscan2
- ABCB1 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.57); catalogued as rs777570345, COSV55944937; called by muse, varscan2
- ABCB1 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.236); catalogued as COSV55944948; called by muse, mutect2, varscan2
- ABCB1 | c.42G>T p.K14N | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1390637727, COSV55944962; called by muse, mutect2, varscan2
- ABCB10 | c.1748C>A p.S583Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100747870, COSV60619703; called by muse, mutect2, varscan2
- ABCB10 | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60619716; called by muse, mutect2, varscan2
- ABCB11 | c.3754G>T p.E1252* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV55585089; called by muse, mutect2, varscan2
- ABCB11 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764581483, CM081482, COSV55585106; called by muse, mutect2, varscan2
- ABCB11 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV55585123; called by muse, mutect2, varscan2
- ABCB4 | c.3732G>T p.Q1244H (on ENST00000265723 / NM_018849.3; = p.Q1237H on NM_000443.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV55931867; called by muse, mutect2, varscan2
- ABCB4 | c.460T>G p.F154V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55931884; called by muse, mutect2
- ABCB5 | c.2710C>T p.L904F (on ENST00000404938 / NM_001163941.2; = p.L459F on NM_178559.6) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1234837911, COSV51702902; called by muse, mutect2, varscan2
- ABCB5 | c.3058G>T p.V1020F (on ENST00000404938 / NM_001163941.2; = p.V575F on NM_178559.6) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV51702910; called by muse, mutect2, varscan2
- ABCB7 | c.2215G>T p.E739* (on ENST00000373394 / NM_001271696.3; = p.E740* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as COSV53717826; called by muse, mutect2, varscan2
- ABCB9 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV54890093; called by muse, mutect2, varscan2
- ABCC1 | c.2254A>C p.I752L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.536); catalogued as COSV60680036; called by muse, mutect2, varscan2
- ABCC11 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62321198; called by muse, mutect2, varscan2
- ABCC12 | c.2476-1G>T p.X826_splice | Splice Site (SNP) | VAF 20/53 reads (38%) | catalogued as COSV60911500; called by muse, mutect2, varscan2
- ABCC12 | c.1756A>C p.S586R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100252327; called by muse, mutect2
- ABCC12 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV60911505; called by muse, mutect2, varscan2
- ABCC2 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs775410341, COSV64984500; called by muse, varscan2
- ABCC3 | c.1260C>A p.F420L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV53317090; called by muse, mutect2, varscan2
- ABCC4 | c.1563G>T p.E521D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV65309566; called by muse, mutect2, varscan2
- ABCC5 | c.4096T>G p.L1366V | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV55586978; called by muse, mutect2, varscan2
- ABCC8 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV56846039, COSV56852803; called by muse, mutect2, varscan2
- ABCD2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58049390; called by muse, mutect2, varscan2
- ABCE1 | c.674T>G p.F225C | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56846145; called by muse, mutect2, varscan2
- ABCF2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 162/465 reads (35%) | catalogued as COSV55180896; called by muse, mutect2, varscan2
- ABCG5 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.467); catalogued as rs776365033, COSV53209414; called by muse, varscan2
- ABHD13 | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.173); catalogued as COSV65534317; called by muse, mutect2, varscan2
- ABHD8 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53112525; called by muse, varscan2
- ABI1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.764); catalogued as rs1231592952, COSV100697784; called by muse, mutect2
- ABI2 | c.1059G>T p.M353I (on ENST00000295851 / NM_001375719.1; = p.M286I on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.832); catalogued as COSV53689741; called by muse, mutect2, varscan2
- ABL2 | c.1209G>T p.K403N (on ENST00000502732 / NM_007314.4; = p.K388N on NM_005158.5) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs776373214, COSV61010981; called by muse, mutect2, varscan2
- ABLIM1 | c.1042-1G>T p.X348_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV53299534; called by muse, mutect2, varscan2
- ABLIM3 | c.138C>A p.C46* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV58639149; called by muse, mutect2, varscan2
- ABRA | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778019842, COSV61731874; called by muse, mutect2, varscan2
- ABRAXAS2 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53715962; called by muse, mutect2, varscan2
- AC005833.1 | c.1216A>C p.T406P | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated, low confidence (0.05); catalogued as COSV52894487; called by muse, mutect2, varscan2
- AC011462.1 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV60531233; called by muse, mutect2, varscan2
- AC013489.1 | c.1215A>C p.E405D | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV51550089; called by muse, mutect2, varscan2
- AC090517.4 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV50995748; called by muse, mutect2, varscan2
- AC090517.4 | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs1305618283, COSV50995754; called by muse, mutect2, varscan2
- AC100868.1 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV51837690; called by muse, mutect2, varscan2
- AC244197.3 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV61711168; called by muse, mutect2, varscan2
- ACAA1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57169853; called by muse, mutect2, varscan2
- ACAA2 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV53269906; called by muse, mutect2, varscan2
- ACACA | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1348929671; called by muse, mutect2, varscan2
- ACACA | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs779594669; called by muse, mutect2, varscan2
- ACACB | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.011); catalogued as rs373214045; called by muse, mutect2, varscan2
- ACACB | c.4422T>G p.F1474L | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV58127941; called by muse, mutect2, varscan2
- ACAD11 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV53893422; called by muse, mutect2, varscan2
- ACAD9 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV58306418, COSV58306465; called by muse, mutect2, varscan2
- ACAD9 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as COSV58306434; called by muse, mutect2, varscan2
- ACAD9 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV58306444; called by muse, mutect2, varscan2
- ACBD5 | c.250A>C p.K84Q (on ENST00000375888 / NM_001352568.1; = p.K86Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV65517917; called by muse, mutect2, varscan2
- ACE2 | c.1256A>C p.K419T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as rs1209307377, COSV53023570; called by muse, mutect2, varscan2
- ACER1 | c.596G>T p.R199M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV56834648; called by muse, mutect2, varscan2
- ACKR1 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as rs759884752, COSV63671663; called by muse, mutect2, varscan2
- ACKR4 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV51442084, COSV51442144; called by muse, mutect2, varscan2
- ACKR4 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51442101; called by muse, mutect2, varscan2
- ACOT12 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as rs766228561, COSV56892438; called by muse, mutect2, varscan2
- ACOXL | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100489980; called by muse, varscan2
- ACP5 | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV54535226; called by muse, mutect2, varscan2
- ACP6 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65076171; called by muse, varscan2
- ACRBP | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1308181351, COSV57523006; called by muse, mutect2, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by muse, varscan2
- ACSF2 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.026); catalogued as COSV51970900; called by muse, mutect2, varscan2
- ACSF3 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs529560098, COSV58076490; called by muse, mutect2, varscan2
- ACSL1 | c.1956+1G>A p.X652_splice | Splice Site (SNP) | VAF 27/91 reads (30%) | catalogued as COSV55660565; called by muse, mutect2, varscan2
- ACSL4 | c.530-1G>A p.X177_splice (on ENST00000340800 / NM_022977.2; = p.X136_splice on NM_004458.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 30/95 reads (32%) | catalogued as COSV61613216; called by muse, mutect2, varscan2
- ACSL6 | c.15G>T p.E5D (on ENST00000379240; = p.E30D on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV57294298; called by muse, mutect2, varscan2
- ACSM2B | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV61656647; called by muse, mutect2, varscan2
- ACSM3 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55499734; called by muse, mutect2, varscan2
- ACSM3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755942547, COSV55499745; called by muse, mutect2, varscan2
- ACSM3 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.118); catalogued as rs1346066860, COSV55499758; called by muse, mutect2, varscan2
- ACTA2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs397516684, CM145697, COSV56515587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTL6A | c.1087A>G p.R363G | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66998626; called by muse, mutect2, varscan2
- ACTL6B | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV50513834; called by muse, mutect2, varscan2
- ACTL8 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV64862700; called by muse, mutect2, varscan2
- ACTL8 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV64860156; called by muse, mutect2, varscan2
- ACTL9 | c.1134C>A p.F378L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV61004586; called by muse, mutect2
- ACTR2 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53199469; called by muse, mutect2, varscan2
- ACTR3B | c.666G>T p.E222D | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs756414856, COSV55446173; called by muse, mutect2, varscan2
- ACVR2A | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV54018949; called by muse, mutect2, varscan2
- ACVR2B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV61701072; called by muse, mutect2, varscan2
- ADA2 | c.889G>T p.D297Y (on ENST00000262607; = p.D56Y on NM_177405.3) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs766661729, COSV52830245; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, mutect2, varscan2
- ADAD1 | c.932C>A p.S311Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56641086, COSV56641429, COSV99636010; called by muse, mutect2, varscan2
- ADAM12 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64102410, COSV64113684; called by muse, mutect2, varscan2
- ADAM15 | c.979T>G p.F327V | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.314); catalogued as COSV55125182; called by muse, mutect2, varscan2
- ADAM15 | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 49/176 reads (28%) | catalogued as rs757099799, COSV55125191; called by muse, mutect2, varscan2
- ADAM18 | c.1568C>A p.S523Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.642); catalogued as rs781004298, COSV55843581; called by muse, mutect2, varscan2
- ADAM20 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1361391168, COSV56454038; called by muse, mutect2, varscan2
- ADAM22 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs535039786, COSV55969346; called by muse, mutect2, varscan2
- ADAM22 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1392077259, COSV55969378; called by muse, mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAM23 | c.1120A>G p.K374E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52207517; called by muse, mutect2, varscan2
- ADAM23 | c.1362A>C p.E454D | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52207552; called by muse, varscan2
- ADAM29 | c.1445A>C p.E482A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV63660091; called by muse, mutect2, varscan2
- ADAM32 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs567675296, COSV65946823; called by muse, mutect2, varscan2
- ADAM7 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV51534848; called by muse, mutect2, varscan2
- ADAM8 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs376606595; called by muse, mutect2, varscan2
- ADAMDEC1 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56474262; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.11); catalogued as rs867213776, COSV56474020; called by muse, mutect2, varscan2
- ADAMTS12 | c.4514A>C p.K1505T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs758958823, COSV61255285; called by muse, mutect2, varscan2
- ADAMTS14 | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV64599550; called by muse, mutect2, varscan2
- ADAMTS14 | c.3178+1G>T p.X1060_splice | Splice Site (SNP) | VAF 23/81 reads (28%) | catalogued as COSV64599561; called by muse, mutect2, varscan2
- ADAMTS16 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1366390597, COSV56977689; called by muse, mutect2, varscan2
- ADAMTS16 | c.2590A>C p.K864Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV56977715; called by muse, mutect2
- ADAMTS19 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV50731882; called by muse, varscan2
- ADAMTS2 | c.3168G>T p.K1056N | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV52364501; called by muse, mutect2, varscan2
- ADAMTS3 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54384393, COSV99710646; called by muse, mutect2, varscan2
- ADAMTS3 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV54384404; called by muse, mutect2, varscan2
- ADAMTS3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1017254734, COSV54384432; called by muse, mutect2, varscan2
- ADAMTS8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs775536904, COSV57291111; called by muse, mutect2, varscan2
- ADAMTS9 | c.3085A>C p.N1029H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99898972; called by muse, mutect2
- ADAMTS9 | c.3083G>A p.R1028Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs772805812, COSV99898978; called by muse, mutect2
- ADAMTS9 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55774786; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as COSV99717585; called by muse, mutect2
- ADAR | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99425652; called by muse, mutect2
- ADCK1 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53078338; called by muse, mutect2, varscan2
- ADCK2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.052); catalogued as COSV50780707; called by muse, mutect2, varscan2
- ADCY1 | c.2259G>T p.M753I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52029900; called by muse, mutect2, varscan2
- ADCY10 | c.3111C>A p.F1037L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV63238491; called by muse, varscan2
- ADCY10 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748485936, COSV63238492; called by muse, mutect2, varscan2
- ADCY4 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1283804610, COSV60251875; called by muse, mutect2, varscan2
- ADCY4 | c.1981G>T p.G661* | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV60251779, COSV60251890; called by muse, mutect2, varscan2
- ADCY5 | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1397131565, COSV100568098, COSV59193958, COSV59200585; called by muse, mutect2, varscan2
- ADCY5 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs116775208; called by muse, mutect2, varscan2
- ADCY9 | c.2999T>G p.F1000C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53571397; called by muse, mutect2, varscan2
- ADCY9 | c.2520-1G>T p.X840_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV53571403; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); catalogued as rs1307857192, COSV100416360, COSV58441241; called by muse, mutect2, varscan2
- ADD1 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as COSV53266236; called by muse, mutect2, varscan2
- ADD2 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); catalogued as COSV52454691; called by muse, mutect2, varscan2
- ADGRB2 | c.3613C>A p.L1205M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV57070460; called by muse, mutect2, varscan2
- ADGRB3 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV65382171; called by muse, mutect2, varscan2
- ADGRB3 | c.1073C>A p.S358* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV65382173; called by muse, mutect2, varscan2
- ADGRB3 | c.1823G>T p.R608I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs747988050, COSV101000147, COSV65382174; called by muse, varscan2
- ADGRB3 | c.3626C>A p.A1209E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as COSV99484121; called by muse, mutect2, varscan2
- ADGRE1 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV51671815; called by muse, mutect2, varscan2
- ADGRE2 | c.2466T>G p.V822= | Splice Region (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100215803; called by muse, mutect2, varscan2
- ADGRF1 | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV51943826; called by muse, mutect2, varscan2
- ADGRF1 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV64799459; called by muse, mutect2, varscan2
- ADGRF2 | c.1127G>T p.R376I (on ENST00000296862 / NM_001368115.2; = p.R308I on NM_153839.7) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs368691313, COSV57286389; called by muse, mutect2, varscan2
- ADGRF4 | c.152A>T p.K51I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV51949454, COSV51956820, COSV99348243; called by muse, varscan2
- ADGRF5 | c.2492G>T p.R831I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51929642; called by mutect2, varscan2
- ADGRF5 | c.307T>G p.L103V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99345132; called by muse, mutect2
- ADGRF5 | c.39T>G p.F13L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759318818, COSV51929657; called by muse, varscan2
- ADGRG2 | c.2714C>A p.S905Y (on ENST00000379869 / NM_001079858.3; = p.S902Y on NM_005756.4) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61337415; called by muse, mutect2, varscan2
- ADGRG2 | c.415-1G>T p.X139_splice (on ENST00000379869 / NM_001079858.3; = p.X136_splice on NM_005756.4) | Splice Site (SNP) | VAF 8/85 reads (9%) | catalogued as COSV100491931, COSV61337428; called by muse, mutect2, varscan2
- ADGRG2 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV61337435; called by muse, mutect2, varscan2
- ADGRG3 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59650108; called by muse, mutect2, varscan2
- ADGRG4 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV54949094; called by muse, mutect2, varscan2
- ADGRG4 | c.1965T>G p.I655M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs1337662388, COSV54949103; called by muse, mutect2, varscan2
- ADGRG4 | c.3452A>G p.D1151G | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV54949111; called by muse, mutect2, varscan2
- ADGRG4 | c.5045C>A p.S1682Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV54949124; called by muse, mutect2, varscan2
- ADGRG4 | c.5849G>A p.G1950E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99794246; called by muse, mutect2
- ADGRG4 | c.7473G>T p.K2491N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV54949144; called by muse, mutect2, varscan2
- ADGRG4 | c.8908T>G p.L2970V | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54949165; called by muse, mutect2, varscan2
- ADGRG6 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51586249, COSV51598146; called by muse, mutect2, varscan2
- ADGRG7 | c.235T>G p.F79V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV56293572; called by muse, mutect2, varscan2
- ADGRG7 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV56293582; called by muse, mutect2, varscan2
- ADGRL1 | c.3448C>T p.R1150W (on ENST00000340736 / NM_001008701.3; = p.R1145W on NM_014921.5) | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61563541; called by muse, mutect2, varscan2
- ADGRL3 | c.2414G>A p.R805Q (on ENST00000506720 / NM_001322402.2; = p.R737Q on NM_015236.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs770571932, COSV72229230; called by muse, mutect2, varscan2
- ADGRL3 | c.3665C>A p.S1222* (on ENST00000506720 / NM_001322402.2; = p.S1154* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV72229233; called by muse, varscan2
- ADGRV1 | c.5547A>C p.Q1849H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV67978225; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.13046T>G p.F4349C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101315625; called by muse, mutect2
- ADH1C | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV72624780; called by muse, varscan2
- ADH7 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as rs769616843, COSV52919625, COSV52923689; called by muse, mutect2, varscan2
- ADIG | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV64893578; called by muse, mutect2, varscan2
- ADPRM | c.399T>G p.D133E | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.478); catalogued as COSV65754350; called by muse, mutect2, varscan2
- ADRA2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787168; called by muse, mutect2, varscan2
- ADRB3 | c.200G>T p.R67I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61461445; called by muse, mutect2, varscan2
- ADSL | c.1450C>A p.L484M | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV50651186; called by muse, mutect2, varscan2
- ADSS2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV63694472; called by muse, mutect2, varscan2
- AEBP1 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs749154733, COSV56255132; called by muse, mutect2, varscan2
- AEBP2 | c.1313G>T p.R438I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56861458; called by muse, mutect2, varscan2
- AFAP1L1 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57043773; called by muse, varscan2
- AFDN | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs756198307, COSV60037315; called by muse, mutect2, varscan2
- AFF2 | c.1670C>A p.S557Y | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV53976027, COSV53990806; called by muse, varscan2
- AFF4 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1259299926, COSV54791367; called by muse, mutect2, varscan2
- AFM | c.405T>G p.F135L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99888616; called by muse, varscan2
- AGAP3 | c.1600G>T p.D534Y (on ENST00000622464; = p.D570Y on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV68243200; called by muse, mutect2, varscan2
- AGAP6 | c.1279G>A p.E427K (on ENST00000374056 / NM_001365867.1; = p.E450K on NM_001077665.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs781900073, COSV65017307; called by muse, mutect2, varscan2
- AGBL1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs759370949, COSV69792431; called by muse, mutect2, varscan2
- AGBL5 | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.329); catalogued as COSV59935463; called by muse, mutect2, varscan2
- AGBL5 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV59935469; called by muse, mutect2, varscan2
- AGBL5 | c.2585G>T p.S862I | Missense Mutation (SNP) | VAF 138/453 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as COSV64079026; called by muse, mutect2, varscan2
- AGFG1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV59510083, COSV59513107; called by muse, mutect2, varscan2
- AGFG2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53543923; called by muse, mutect2, varscan2
- AGL | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99648748; called by muse, mutect2
- AGL | c.1836A>C p.L612F | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54047921; called by muse, mutect2, varscan2
- AGO3 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs1244575080, COSV55790721, COSV55792811; called by muse, mutect2, varscan2
- AGPS | c.1472T>G p.F491C | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51560820; called by muse, mutect2, varscan2
- AGR2 | c.204-1G>T p.X68_splice | Splice Site (SNP) | VAF 28/103 reads (27%) | catalogued as COSV68596093; called by muse, mutect2, varscan2
- AGT | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs1334147335, COSV64183680; called by muse, mutect2, varscan2
- AGTPBP1 | c.2541C>A p.H847Q (on ENST00000357081 / NM_001330701.2; = p.H807Q on NM_015239.2) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61268448; called by muse, mutect2, varscan2
- AGTPBP1 | c.1553G>T p.R518I (on ENST00000357081 / NM_001330701.2; = p.R478I on NM_015239.2) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV61268456; called by muse, mutect2, varscan2
- AHCTF1 | c.5446G>T p.E1816* (on ENST00000366508; = p.E1790* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV58245701; called by mutect2, varscan2
- AHDC1 | c.3357G>A p.W1119* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55936644, COSV99899505; called by muse, mutect2, varscan2
- AHNAK | c.16120C>A p.L5374M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV57203393; called by muse, mutect2, varscan2
- AHNAK | c.7836A>C p.E2612D | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV99946247; called by muse, mutect2
- AHNAK2 | c.9942G>T p.K3314N | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60907423, COSV60923497; called by muse, varscan2
- AHNAK2 | c.9935A>C p.K3312T | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV60907430; called by muse, varscan2
- AHR | c.2105C>A p.S702Y | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as COSV54121555; called by muse, mutect2, varscan2
- AIF1L | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as COSV55988982; called by muse, mutect2, varscan2
- AIFM3 | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV58997390; called by muse, mutect2, varscan2
- AK5 | c.565A>G p.T189A (on ENST00000354567 / NM_174858.3; = p.T163A on NM_012093.4) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as rs148313492; called by muse, mutect2, varscan2
- AK5 | c.754G>T p.E252* (on ENST00000354567 / NM_174858.3; = p.E226* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV60967421; called by muse, mutect2, varscan2
- AK8 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as rs375128507; called by mutect2, varscan2
- AKAP11 | c.1683T>A p.S561R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50292513; called by muse, mutect2, varscan2
- AKAP12 | c.493T>G p.S165A | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53570073; called by muse, mutect2, varscan2
- AKAP13 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV63459068; called by muse, mutect2, varscan2
- AKAP13 | c.6156C>A p.F2052L (on ENST00000394518 / NM_007200.5; = p.F2056L on NM_006738.6) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV63448047; called by muse, mutect2, varscan2
- AKAP14 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs978267657, COSV57629200; called by muse, mutect2, varscan2
- AKAP4 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV62073627; called by muse, mutect2, varscan2
- AKAP6 | c.2968A>G p.M990V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as rs1421930067, COSV55204651; called by muse, mutect2, varscan2
- AKAP6 | c.3824C>A p.S1275* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55204663; called by muse, varscan2
- AKAP9 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV62338464; called by muse, mutect2, varscan2
- AKAP9 | c.4584T>G p.I1528M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62338476; called by muse, varscan2
- AKR1C2 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138437499; called by muse, mutect2, varscan2
- AKR1D1 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54336083; called by muse, mutect2, varscan2
- AL121899.2 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV67349614; called by muse, mutect2, varscan2
- ALDH1A1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); catalogued as COSV52789066; called by muse, mutect2, varscan2
- ALDH1L1 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs550440307, COSV56410533, COSV56414628; called by muse, mutect2, varscan2
- ALDH3A1 | c.711C>A p.F237L | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV56734260; called by muse, mutect2, varscan2
- ALDH5A1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750638943, COSV62372720; called by muse, mutect2, varscan2
- ALDH8A1 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640097; called by muse, mutect2, varscan2
- ALG10B | c.671A>C p.K224T | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV58142227; called by muse, mutect2
- ALG6 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 61/159 reads (38%) | catalogued as COSV54763161; called by muse, mutect2, varscan2
- ALG9 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101211859; called by muse, mutect2
- ALG9 | c.915C>A p.F305L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67643455; called by muse, mutect2, varscan2
- ALKBH6 | c.87C>A p.F29L (on ENST00000252984 / NM_001297701.2; = p.F57L on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53323945; called by muse, mutect2, varscan2
- ALMS1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as COSV52502437; called by muse, mutect2, varscan2
- ALMS1 | c.7649A>G p.H2550R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52502450; called by muse, mutect2, varscan2
- ALMS1 | c.11161C>A p.L3721M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267599449, COSV52502459; called by muse, mutect2, varscan2
- ALOX12 | c.1913T>G p.I638S | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52348478; called by muse, varscan2
- ALOX15 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs149366613; called by mutect2, varscan2
- ALOX5 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1047630934, COSV65550945; called by muse, mutect2, varscan2
- ALOXE3 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV59073935; called by muse, mutect2, varscan2
- ALPI | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55013363; called by muse, mutect2, varscan2
- ALPK2 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs370248466, COSV64490192; called by muse, mutect2, varscan2
- ALPK2 | c.3812A>C p.K1271T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV64490199; called by muse, mutect2, varscan2
- ALPK2 | c.2378A>C p.D793A | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV64490206; called by muse, mutect2, varscan2
- ALPK3 | c.2004G>T p.E668D | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as COSV51929110; called by muse, mutect2, varscan2
- ALS2 | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.232); catalogued as COSV51883937; called by muse, mutect2, varscan2
- AMBN | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV59825108, COSV59825190, COSV59825299; called by muse, mutect2, varscan2
- AMBN | c.770T>G p.L257R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV59825116; called by muse, mutect2, varscan2
- AMDHD1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.075); catalogued as COSV57137668; called by muse, varscan2
- AMDHD1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 26/212 reads (12%) | catalogued as COSV57137678; called by muse, varscan2
- AMER1 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1179031603, COSV57654693; called by muse, mutect2, varscan2
- AMER1 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV57654710; called by muse, mutect2, varscan2
- AMIGO2 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV56973254; called by muse, mutect2, varscan2
- AMIGO2 | c.637A>C p.N213H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56973269; called by muse, mutect2, varscan2
- AMPD1 | c.2068A>G p.T690A | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62414981; called by muse, mutect2, varscan2
- AMPH | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs151055033; called by muse, mutect2, varscan2
- AMY2A | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70214255; called by muse, mutect2, varscan2
- AMZ1 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV56684763; called by muse, mutect2, varscan2
- AMZ2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs77434249, COSV63083548; called by muse, varscan2
- ANGPT2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57334841; called by muse, mutect2, varscan2
- ANGPTL3 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.556); catalogued as COSV51995482; called by muse, mutect2, varscan2
- ANGPTL5 | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV100528064, COSV57531748; called by muse, mutect2, varscan2
- ANK2 | c.5264C>A p.S1755Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52145274; called by muse, mutect2, varscan2
- ANK2 | c.7577C>T p.S2526L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762909298, COSV52145283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.10454C>A p.S3485Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); catalogued as COSV55043627; called by muse, mutect2, varscan2
- ANK3 | c.10063T>C p.S3355P | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV55043636; called by muse, mutect2, varscan2
- ANK3 | c.9845T>G p.I3282S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV55043640, COSV55063154; called by muse, mutect2, varscan2
- ANK3 | c.7319T>G p.L2440R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV55043647; called by muse, mutect2, varscan2
- ANKAR | c.872G>T p.R291I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1559065778, COSV55609359; called by muse, mutect2, varscan2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 50/145 reads (34%) | catalogued as rs774211930, COSV65691928; called by muse, mutect2, varscan2
- ANKH | c.755G>T p.R252I | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV52476807; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.364T>A p.S122T | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV51840294; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7416T>G p.I2472M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.009); catalogued as COSV51840358; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7697G>A p.R2566Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs368740046; called by muse, mutect2, varscan2
- ANKRA2 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV57140459; called by muse, mutect2, varscan2
- ANKRD11 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV56354566; called by muse, mutect2, varscan2
- ANKRD12 | c.1847T>G p.F616C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.41); catalogued as COSV100040948; called by muse, mutect2
- ANKRD12 | c.2282C>A p.S761Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.243); catalogued as COSV50819090; called by muse, varscan2
- ANKRD12 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs766734820, COSV50819104; called by muse, mutect2, varscan2
- ANKRD12 | c.5921A>C p.K1974T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50819110; called by muse, mutect2, varscan2
- ANKRD13C | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 49/163 reads (30%) | catalogued as COSV52029052; called by muse, mutect2, varscan2
- ANKRD16 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV51946660; called by muse, mutect2, varscan2
- ANKRD17 | c.7547A>G p.Q2516R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV58215271; called by muse, mutect2, varscan2
- ANKRD17 | c.6570G>T p.K2190N | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.051); catalogued as COSV58215279, COSV58225548; called by muse, mutect2, varscan2
- ANKRD17 | c.4527C>A p.N1509K | Missense Mutation (SNP) | VAF 126/427 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.109); catalogued as COSV58215290; called by muse, mutect2, varscan2
- ANKRD17 | c.2574A>C p.Q858H | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV58215296; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1975T>C p.F659L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1364358152; called by muse, varscan2
- ANKRD20A4P | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV100628448; called by mutect2, varscan2
- ANKRD22 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs758073859, COSV64236209; called by muse, mutect2
- ANKRD23 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV58412154; called by muse, mutect2, varscan2
- ANKRD24 | c.531A>C p.Q177H | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV53667553; called by muse, mutect2, varscan2
- ANKRD26 | c.3072G>T p.E1024D | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV65773933; called by muse, mutect2, varscan2
- ANKRD28 | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV67516845; called by muse, varscan2
- ANKRD28 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV67516849; called by muse, varscan2
- ANKRD30A | c.1654T>C p.F552L (on ENST00000611781; = p.F496L on NM_052997.2) | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.827); catalogued as rs1222036186, COSV64603637; called by muse, mutect2, varscan2
- ANKRD30A | c.1786G>T p.G596* (on ENST00000611781; = p.G540* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV64603643; called by muse, varscan2
- ANKRD34A | c.1460G>T p.S487I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV60162032; called by mutect2, varscan2
- ANKRD34B | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as COSV58613337; called by muse, mutect2, varscan2
- ANKRD44 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as rs778147827, COSV56549225; called by muse, mutect2, varscan2
- ANKRD49 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57059788; called by muse, mutect2, varscan2
- ANKRD50 | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs759095901, COSV72385021; called by muse, mutect2, varscan2
- ANKRD54 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV99316399; called by muse, mutect2
- ANKRD7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV54553824; called by muse, mutect2, varscan2
- ANKS1B | c.3206C>A p.S1069Y (on ENST00000547776 / NM_152788.4; = p.S235Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59116214; called by muse, mutect2, varscan2
- ANKS1B | c.1224A>C p.L408F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV61334481; called by muse, mutect2, varscan2
- ANKS1B | c.1030T>C p.S344P | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV61334486; called by muse, mutect2, varscan2
- ANKS4B | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs751887530, COSV61138694; called by muse, mutect2, varscan2
- ANKS4B | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV61138701; called by muse, mutect2, varscan2
- ANKS6 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as rs775835091, COSV62048792; called by muse, mutect2, varscan2
- ANLN | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV104379682, COSV56073795; called by muse, mutect2, varscan2
- ANLN | c.1949G>T p.R650I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56073804, COSV56076463; called by muse, mutect2, varscan2
- ANO2 | c.2587G>A p.E863K (on ENST00000356134 / NM_001278597.3; = p.E867K on NM_001278596.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.099); catalogued as COSV59007397, COSV59012960; called by muse, mutect2, varscan2
- ANO3 | c.1299T>G p.I433M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56779987; called by muse, mutect2, varscan2
- ANO4 | c.230C>A p.S77Y (on ENST00000392977 / NM_001286615.2; = p.S42Y on NM_178826.4) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV54585078; called by muse, varscan2
- ANO4 | c.1054G>C p.A352P (on ENST00000392977 / NM_001286615.2; = p.A317P on NM_178826.4) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54585088, COSV54619251; called by muse, mutect2, varscan2
- ANO4 | c.2546C>T p.S849L (on ENST00000392977 / NM_001286615.2; = p.S814L on NM_178826.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376008571, COSV54610752; called by muse, mutect2, varscan2
- ANO5 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201595; called by muse, mutect2, varscan2
- ANO5 | c.1704T>G p.F568L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.345); catalogued as COSV61081943; called by muse, mutect2, varscan2
- ANO5 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs886042760, COSV61081922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO6 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57656543; called by muse, mutect2, varscan2
- ANTXR1 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV58008892; called by muse, mutect2, varscan2
- ANTXR1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 45/171 reads (26%) | catalogued as COSV58008912; called by muse, mutect2, varscan2
- ANXA7 | c.1337G>A p.R446Q (on ENST00000372919 / NM_001320880.2; = p.R424Q on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65822881; called by muse, mutect2, varscan2
- ANXA9 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776885513, COSV56497500; called by muse, mutect2, varscan2
- AOAH | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs758294905, COSV51735449; called by muse, mutect2, varscan2
- AOC2 | c.2118C>A p.F706L (on ENST00000253799 / NM_009590.4; = p.F679L on NM_001158.5) | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs772005140, COSV53824129, COSV53826096; called by muse, mutect2, varscan2
- AOX1 | c.3545A>C p.N1182T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV53495309; called by muse, mutect2, varscan2
- AP002512.3 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.39); catalogued as rs1326016320, COSV56565765; called by muse, mutect2, varscan2
- AP1G1 | c.1606C>T p.R536* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV55485262; called by muse, mutect2, varscan2
- AP1G1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55485296; called by muse, varscan2
- AP1G2 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs759104775, COSV55337301, COSV55339360; called by muse, mutect2, varscan2
- AP1M2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs773360506, COSV51565455; called by muse, mutect2, varscan2
- AP2A2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59958011; called by muse, mutect2, varscan2
- AP3B1 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 57/190 reads (30%) | catalogued as COSV54876236; called by muse, mutect2, varscan2
- AP3B1 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54876250; called by muse, mutect2, varscan2
- AP3D1 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs746654797, COSV61424423; called by muse, mutect2, varscan2
- AP4B1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs145803736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP4E1 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV55914954; called by muse, mutect2, varscan2
- AP5M1 | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV55104422; called by muse, mutect2, varscan2
- APAF1 | c.574A>G p.K192E (on ENST00000551964 / NM_181861.2; = p.K181E on NM_001160.3) | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59661542; called by muse, mutect2, varscan2
- APAF1 | c.2038A>C p.K680Q (on ENST00000551964 / NM_181861.2; = p.K669Q on NM_001160.3) | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV59661553; called by muse, mutect2, varscan2
- APAF1 | c.2794G>T p.E932* (on ENST00000551964 / NM_181861.2; = p.E878* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV59661562; called by muse, mutect2, varscan2
- APBA1 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55221469; called by muse, mutect2, varscan2
- APBB2 | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV55946901; called by muse, mutect2, varscan2
- APC | c.2185C>T p.L729F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX983260, COSV57324183; called by muse, mutect2, varscan2
- APC | c.4630G>T p.E1544* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV57327947, COSV57331833, COSV57342321, COSV57357142; called by muse, mutect2
- APC | c.4901C>T p.P1634L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as rs370433763, COSV57324196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEH | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs779678983, COSV56531982; called by muse, mutect2, varscan2
- API5 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV66632359; called by muse, mutect2, varscan2
- APLF | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV100376743, COSV58142399; called by muse, mutect2, varscan2
- APLNR | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.288); catalogued as COSV57241357; called by muse, mutect2, varscan2
- APLP1 | c.1895G>A p.R632H (on ENST00000221891 / NM_001024807.3; = p.R631H on NM_005166.4) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55701609; called by muse, mutect2, varscan2
- APLP2 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776642613, COSV53838788; called by muse, mutect2, varscan2
- APOA1 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as rs1373700967, CM108780, COSV52635247; called by muse, mutect2, varscan2
- APOB | c.12826T>G p.L4276V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV51922756; called by muse, mutect2, varscan2
- APOB | c.10012A>G p.T3338A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51922764; called by muse, varscan2
- APOB | c.7897T>G p.F2633V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV51921324, COSV51922778; called by muse, mutect2, varscan2
- APOB | c.1931C>A p.S644Y | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs147173587, COSV51922803, COSV51933707; called by muse, mutect2, varscan2
- APOBEC1 | c.239T>C p.M80T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57548158; called by muse, mutect2, varscan2
- APOBEC3D | c.1046T>G p.F349C | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53325513; called by muse, mutect2, varscan2
- APOBEC4 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58016842; called by muse, mutect2, varscan2
- APOH | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as COSV52771276, COSV52774973; called by muse, mutect2, varscan2
- APOL1 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV59868189; called by muse, mutect2, varscan2
- APOL5 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs369534518, COSV50766354; called by muse, mutect2, varscan2
- APOOL | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV64271049; called by muse, mutect2, varscan2
- APPL1 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV55699577; called by muse, mutect2, varscan2
- APPL1 | c.1469A>C p.K490T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV55699592; called by muse, mutect2, varscan2
- APPL2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as rs1314012568, COSV51588026; called by muse, mutect2, varscan2
- APPL2 | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.373); catalogued as COSV51588037, COSV51589445; called by muse, varscan2
- APTX | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs142133683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP11 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV57991979; called by muse, mutect2, varscan2
- AQP2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs749751111, COSV52228853; called by muse, mutect2, varscan2
- AQP4 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV67218229; called by muse, varscan2
- AQP4 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs528517012, COSV67218235; called by muse, varscan2
- AQR | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV50029523; called by muse, mutect2, varscan2
- AQR | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as COSV50029529, COSV50043410; called by muse, mutect2, varscan2
- AR | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV65952965; called by muse, mutect2, varscan2
- AR | c.2494C>T p.R832* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as CM920090, COSV65952973; called by muse, mutect2, varscan2
- ARAF | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs1439786171, COSV51691155; called by muse, mutect2, varscan2
- ARAF | c.1559T>G p.F520C | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51691162, COSV51693599; called by muse, mutect2, varscan2
- ARAP2 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV58282383; called by muse, mutect2, varscan2
- ARAP2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2, varscan2
- ARAP2 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV58282405; called by muse, varscan2
- ARAP3 | c.3411G>T p.K1137N | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV53348504; called by muse, mutect2, varscan2
- ARAP3 | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as rs201916487, COSV53348515; called by muse, mutect2, varscan2
- ARAP3 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53348533; called by muse, mutect2, varscan2
- AREL1 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 52/137 reads (38%) | catalogued as COSV62665385; called by muse, mutect2, varscan2
- AREL1 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs758829441, COSV62665391; called by muse, mutect2, varscan2
- AREL1 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV62665398; called by muse, mutect2, varscan2
- ARF3 | c.44A>T p.K15M | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV56740844; called by muse, mutect2, varscan2
- ARF4 | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57714666, COSV57715913; called by muse, mutect2, varscan2
- ARFGEF1 | c.3176T>G p.L1059R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV51602258; called by muse, mutect2, varscan2
- ARFGEF2 | c.949C>A p.L317I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV64210373; called by muse, mutect2, varscan2
- ARGLU1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV62271331; called by muse, mutect2, varscan2
- ARHGAP10 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60594762; called by muse, mutect2, varscan2
- ARHGAP10 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 88/277 reads (32%) | catalogued as COSV60594769; called by muse, mutect2, varscan2
- ARHGAP12 | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60961147; called by muse, mutect2, varscan2
- ARHGAP15 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54476321, COSV54477162; called by muse, mutect2, varscan2
- ARHGAP20 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs748439390, COSV52806426; called by muse, mutect2, varscan2
- ARHGAP21 | c.2398T>G p.S800A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57601929; called by muse, mutect2, varscan2
- ARHGAP24 | c.766T>G p.L256V (on ENST00000395184 / NM_001025616.3; = p.L163V on NM_031305.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99981914; called by muse, varscan2
- ARHGAP28 | c.1942C>T p.P648S (on ENST00000383472 / NM_001366230.1; = p.P489S on NM_001010000.3) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV51631318; called by muse, mutect2, varscan2
- ARHGAP29 | c.3737G>A p.R1246Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs769645920, COSV53108042; called by muse, mutect2, varscan2
- ARHGAP29 | c.2871A>C p.Q957H | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV53108054; called by muse, varscan2
- ARHGAP29 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1272527386, COSV53108068; called by muse, mutect2, varscan2
- ARHGAP30 | c.1825T>G p.F609V | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63514790; called by muse, mutect2, varscan2
- ARHGAP31 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV51788958; called by muse, varscan2
- ARHGAP31 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51788971; called by muse, mutect2, varscan2
- ARHGAP31 | c.3467G>T p.R1156M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV51788984; called by muse, mutect2, varscan2
- ARHGAP32 | c.5410C>A p.L1804I (on ENST00000310343 / NM_001378025.1; = p.L1455I on NM_014715.4) | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV59843123; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV52264412; called by muse, mutect2
- ARHGAP44 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs941505398, COSV52389024; called by muse, mutect2, varscan2
- ARHGAP5 | c.3577C>T p.R1193C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs201734513; called by muse, mutect2, varscan2
- ARHGAP6 | c.2177-1G>T p.X726_splice (on ENST00000337414 / NM_013427.3; = p.X523_splice on NM_013423.3) | Splice Site (SNP) | VAF 31/339 reads (9%) | catalogued as COSV100272548; called by muse, mutect2
- ARHGAP9 | c.2014G>T p.E672* (on ENST00000393797 / NM_001319850.2; = p.E653* on NM_032496.4) | Nonsense Mutation (SNP) | VAF 113/326 reads (35%) | catalogued as COSV57357774; called by muse, mutect2, varscan2
- ARHGEF10L | c.3126G>T p.E1042D | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51427550; called by muse, mutect2, varscan2
- ARHGEF12 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV63102487; called by muse, mutect2, varscan2
- ARHGEF12 | c.3550G>T p.E1184* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV63102492; called by muse, mutect2, varscan2
- ARHGEF17 | c.2956G>T p.E986* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55229275; called by muse, mutect2, varscan2
- ARHGEF26 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754708272, COSV62843732; called by muse, mutect2, varscan2
- ARHGEF37 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs199830230; called by muse, mutect2, varscan2
- ARHGEF6 | c.2313G>T p.K771N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.073); catalogued as COSV51687425; called by muse, mutect2, varscan2
- ARHGEF6 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV51687430; called by muse, mutect2, varscan2
- ARHGEF6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as rs926622130, COSV51687440; called by muse, mutect2, varscan2
- ARHGEF6 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51687449; called by muse, varscan2
- ARHGEF6 | c.250-1G>T p.X84_splice | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as COSV51687488; called by muse, mutect2, varscan2
- ARHGEF9 | c.615C>A p.C205* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV53634385; called by muse, varscan2
- ARHGEF9 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53634433; called by muse, varscan2
- ARID2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs140086050, COSV57595654; called by muse, mutect2, varscan2
- ARID5B | c.3392T>G p.F1131C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV54413944; called by muse, mutect2, varscan2
- ARIH1 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as COSV65910337; called by muse, mutect2, varscan2
- ARIH1 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV65910346; called by muse, varscan2
- ARL11 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as rs958511445, COSV56290629; called by muse, mutect2, varscan2
- ARL13A | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 70/369 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV71448231; called by muse, mutect2, varscan2
- ARL14EP | c.461T>G p.F154C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1264437718, COSV99955863; called by muse, varscan2
- ARL15 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs200968142, COSV72288854; called by muse, varscan2
- ARMC2 | c.1073A>C p.K358T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64549951; called by muse, mutect2, varscan2
- ARMC2 | c.1266A>G p.I422M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV64549960; called by muse, mutect2, varscan2
- ARMC2 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as rs749756077, COSV64549964; called by muse, mutect2, varscan2
- ARMC3 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV53056960, COSV99035369; called by muse, mutect2, varscan2
- ARMC4 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53462533, COSV99518274; called by muse, mutect2, varscan2
- ARMC9 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63019339; called by muse, mutect2, varscan2
- ARMCX1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.124); catalogued as COSV100863163; called by muse, mutect2
- ARMCX1 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65704860; called by muse, mutect2, varscan2
- ARMCX2 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as COSV57529180; called by muse, mutect2, varscan2
- ARMCX2 | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV57529186; called by muse, mutect2, varscan2
- ARMCX2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs781812794, COSV57529190; called by muse, mutect2, varscan2
- ARMCX5 | c.1333A>C p.S445R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV55765886; called by muse, mutect2, varscan2
- ARMT1 | c.224T>G p.F75C | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66178337; called by muse, mutect2, varscan2
- ARRDC3 | c.266T>G p.I89S | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV54364432; called by muse, mutect2, varscan2
- ARSK | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV66169185; called by muse, mutect2, varscan2
- ART4 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as rs770694825, COSV57450945; called by muse, mutect2, varscan2
- ARV1 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV59617002; called by muse, mutect2, varscan2
- AS3MT | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 92/264 reads (35%) | catalogued as COSV54915379; called by muse, mutect2, varscan2
- ASAH1 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV50501262; called by muse, mutect2, varscan2
- ASAP1 | c.716A>C p.N239T | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63044230; called by muse, mutect2, varscan2
- ASAP1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100726962; called by muse, mutect2
- ASAP2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55627220; called by muse, mutect2, varscan2
- ASAP2 | c.1464C>T p.L488= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as rs749082822, COSV55627231, COSV55632805; called by muse, mutect2, varscan2
- ASAP3 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as rs148331468; called by muse, mutect2, varscan2
- ASB11 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV60354282, COSV60356455; called by muse, varscan2
- ASB5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751252627, COSV56668485; called by muse, mutect2, varscan2
- ASB6 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.695); catalogued as rs754625342, COSV52964357; called by mutect2, varscan2
- ASCC3 | c.4553G>A p.R1518H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148742449; called by mutect2, varscan2
- ASCC3 | c.3432A>C p.K1144N | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV61225720; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, varscan2
- ASCL3 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV57940870, COSV57940907; called by muse, mutect2, varscan2
- ASH1L | c.8750G>A p.R2917Q (on ENST00000368346 / NM_001366177.2; = p.R2912Q on NM_018489.3) | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs754089160, COSV64212880; called by muse, mutect2, varscan2
- ASH1L | c.4691C>A p.S1564Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.259); catalogued as COSV100853223; called by muse, mutect2
- ASH1L | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 24/154 reads (16%) | catalogued as COSV64205353; called by muse, mutect2, varscan2
- ASH2L | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV51698415; called by muse, mutect2, varscan2
- ASIC3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52502190; called by muse, mutect2, varscan2
- ASNS | c.1420A>C p.I474L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV51550245; called by muse, mutect2, varscan2
- ASNSD1 | c.1471C>A p.L491I | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53622889, COSV53624613; called by muse, mutect2, varscan2
- ASPG | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71933536, COSV71933697; called by muse, mutect2, varscan2
- ASPG | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.22); catalogued as rs766917698, COSV71933537; called by mutect2, varscan2
- ASPH | c.660A>C p.Q220H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.009); catalogued as COSV62857859; called by muse, mutect2, varscan2
- ASPM | c.10112A>C p.K3371T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54124432; called by muse, mutect2, varscan2
- ASPM | c.8917G>T p.E2973* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV54124439; called by muse, varscan2
- ASPM | c.8908G>A p.A2970T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.99); catalogued as COSV54124448; called by muse, varscan2
- ASPM | c.8564G>A p.R2855K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.175); catalogued as rs557887201, COSV54135001; called by muse, mutect2, varscan2
- ASPM | c.8336G>T p.R2779I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54124462; called by muse, mutect2, varscan2
- ASPM | c.7771A>C p.K2591Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.688); catalogued as COSV54124472; called by muse, varscan2
- ASPM | c.7056G>T p.M2352I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.474); catalogued as COSV54124482, COSV54126118; called by muse, varscan2
- ASPM | c.6989G>T p.R2330M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54124497; called by muse, varscan2
- ASPM | c.6043C>A p.H2015N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.119); catalogued as COSV54124507; called by muse, mutect2, varscan2
- ASPM | c.5603G>T p.R1868I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs761106315, COSV54124517; called by muse, mutect2, varscan2
- ASPN | c.759T>G p.I253M | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1304344942, COSV65015822; called by muse, mutect2, varscan2
- ASTE1 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200808262, COSV53907523, COSV53908737; called by muse, mutect2, varscan2
- ASTN1 | c.2605T>C p.S869P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV56061214; called by muse, mutect2, varscan2
- ASTN1 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56061226, COSV99921168; called by muse, mutect2, varscan2
- ASTN2 | c.1918G>T p.E640* (on ENST00000313400 / NM_001365069.1; = p.E589* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV57749984, COSV57765355; called by muse, mutect2, varscan2
- ASXL1 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.172); catalogued as rs762720533, COSV100040028, COSV60102962; called by muse, mutect2, varscan2
- ASXL3 | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV52456886; called by muse, mutect2, varscan2
- ASXL3 | c.3039G>T p.K1013N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV52456899; called by muse, mutect2, varscan2
- ASXL3 | c.4331G>A p.R1444Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs548755448, COSV52456915; called by muse, mutect2, varscan2
- ASZ1 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV52911089; called by muse, mutect2, varscan2
- ATAD2 | c.4099C>T p.R1367C | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1180402683, COSV54877158; called by muse, mutect2, varscan2
- ATAD2B | c.4376G>T p.*1459Lext*56 | Nonstop Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV53194996; called by muse, mutect2, varscan2
- ATAD2B | c.4304G>A p.R1435H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766834206, COSV53195007; called by muse, mutect2, varscan2
- ATAD3B | c.699G>T p.K233N (on ENST00000308647; = p.K339N on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV58019127; called by muse, mutect2, varscan2
- ATAD5 | c.5174C>A p.S1725* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV58971948, COSV58972611; called by muse, mutect2, varscan2
- ATF1 | c.195-1G>T p.X65_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | catalogued as COSV50393955; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATF7 | c.692C>T p.S231L (on ENST00000548446 / NM_001366555.2; = p.S220L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.686); catalogued as rs372435342; called by muse, mutect2, varscan2
- ATG2B | c.5452C>T p.P1818S | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55889392; called by muse, mutect2, varscan2
- ATG2B | c.3643-1G>T p.X1215_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99951979; called by muse, mutect2
- ATG4A | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV58964120; called by muse, mutect2, varscan2
- ATG4C | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV58603602; called by muse, varscan2
- ATG5 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58346067, COSV58347151; called by muse, mutect2, varscan2
- ATL2 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60050335; called by muse, mutect2, varscan2
- ATM | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs3218684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.1708T>C p.F570L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53725477; called by muse, mutect2, varscan2
- ATM | c.3741C>A p.F1247L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53725511; called by muse, mutect2, varscan2
- ATM | c.5047T>G p.F1683V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV53725534; called by muse, mutect2, varscan2
- ATOH1 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV60037366; called by muse, mutect2, varscan2
- ATP10A | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV63513327; called by muse, mutect2, varscan2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, mutect2, varscan2
- ATP11B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV60026901; called by muse, varscan2
- ATP11B | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV60026008; called by muse, mutect2, varscan2
- ATP11C | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV100558335, COSV59559427; called by muse, mutect2, varscan2
- ATP11C | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1033024084, COSV59559449, COSV59565145; called by muse, varscan2
- ATP11C | c.669-1G>T p.X223_splice | Splice Site (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100558145, COSV59559476; called by muse, varscan2
- ATP11C | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV59559500; called by muse, mutect2, varscan2
- ATP11C | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59559521; called by muse, mutect2, varscan2
- ATP12A | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as COSV54512223; called by muse, mutect2, varscan2
- ATP12A | c.3105G>T p.K1035N | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV54512244; called by muse, mutect2, varscan2
- ATP13A3 | c.2435A>C p.K812T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV55461418; called by muse, mutect2, varscan2
- ATP13A4 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61316128; called by muse, mutect2, varscan2
- ATP13A4 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV55065818; called by muse, mutect2, varscan2
- ATP13A5 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60865615; called by muse, varscan2
- ATP1A2 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63402212; called by muse, varscan2
- ATP1A2 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63402218, COSV63402714; called by muse, mutect2, varscan2
- ATP1A3 | c.3038G>A p.R1013H (on ENST00000545399 / NM_001256214.2; = p.R1000H on NM_152296.5) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57484978; called by muse, varscan2
- ATP2A1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV63919919; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP2B1 | c.2609C>A p.A870D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53803742; called by muse, varscan2
- ATP2C1 | c.1742C>A p.A581D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60752446; called by muse, mutect2, varscan2
- ATP2C1 | c.2099A>C p.K700T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as COSV60752457; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 55/183 reads (30%) | catalogued as COSV57747637; called by muse, mutect2, varscan2
- ATP6V0D2 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV53413053; called by muse, varscan2
- ATP6V1B1 | c.1362G>T p.K454N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV52268186, COSV52271131; called by muse, mutect2, varscan2
- ATP6V1C2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 148/444 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs751303993, COSV55357732; called by muse, mutect2, varscan2
- ATP6V1H | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV62216766; called by muse, mutect2, varscan2
- ATP7A | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as CD962747, COSV58442320; called by muse, mutect2, varscan2
- ATP7A | c.2090C>A p.S697Y | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58454729; called by muse, mutect2
- ATP7A | c.3788C>A p.S1263Y | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100430471; called by muse, mutect2, varscan2
- ATP7A | c.3967G>A p.D1323N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58442357; called by muse, varscan2
- ATP8A1 | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.033); catalogued as COSV52528358; called by muse, mutect2, varscan2
- ATP8A1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1188738511, COSV52528382; called by muse, varscan2
- ATP8A2 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.325); catalogued as COSV54936230; called by muse, varscan2
- ATP8B1 | c.2744G>A p.G915E | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99377003; called by mutect2, varscan2
- ATP8B1 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758746529, COSV52172880, COSV52179087; called by muse, mutect2, varscan2
- ATP8B2 | c.1514C>T p.S505F (on ENST00000672630; = p.S472F on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59244682; called by muse, mutect2, varscan2
- ATP8B3 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as rs774266302, COSV59539890, COSV59540759; called by muse, mutect2, varscan2
- ATP8B3 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as rs777333038, COSV59539910; called by muse, mutect2, varscan2
- ATP8B4 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52708947; called by muse, varscan2
- ATP9A | c.2695A>G p.K899E | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV58762918; called by muse, mutect2, varscan2
- ATP9A | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs761097614, COSV100124509, COSV58762928; called by muse, mutect2, varscan2
- ATRNL1 | c.1514A>G p.E505G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs201880985, COSV61796808; called by muse, mutect2, varscan2
- ATRNL1 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV61796811; called by muse, mutect2, varscan2
- ATRNL1 | c.2894G>T p.S965I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV58073576; called by muse, mutect2, varscan2
- ATRX | c.5024A>G p.D1675G | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV64871222; called by muse, mutect2, varscan2
- ATRX | c.3905G>T p.R1302I | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV64871229; called by muse, mutect2, varscan2
- ATRX | c.2441C>A p.S814Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64871234; called by muse, mutect2, varscan2
- ATXN2 | c.2505A>T p.K835N (on ENST00000550104; = p.K675N on NM_002973.4) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV66481187; called by muse, mutect2, varscan2
- ATXN2 | c.782G>A p.G261E (on ENST00000550104; = p.G101E on NM_002973.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66481196; called by muse, mutect2, varscan2
- ATXN2L | c.1888A>C p.S630R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV57365064; called by muse, mutect2, varscan2
- ATXN7 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 45/133 reads (34%) | catalogued as rs940227869, COSV55758194; called by muse, mutect2
- AUP1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); catalogued as COSV57815939; called by muse, mutect2
- AURKA | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.828); catalogued as COSV57167301, COSV57168231; called by muse, mutect2, varscan2
- AVEN | c.1008C>G p.N336K | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV60732128; called by muse, mutect2, varscan2
- AWAT1 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.575); catalogued as rs1041548786, COSV65738134; called by muse, mutect2, varscan2
- AXL | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV56563604; called by muse, mutect2, varscan2
- AXL | c.2274T>G p.I758M (on ENST00000301178 / NM_021913.5; = p.I749M on NM_001699.6) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); catalogued as COSV56563621; called by muse, mutect2, varscan2
- AZI2 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55422688; called by muse, mutect2, varscan2
- AZIN1 | c.411T>G p.I137M | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61479217; called by muse, mutect2, varscan2
- AZU1 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.644); catalogued as COSV52140138, COSV99297438; called by muse, mutect2, varscan2
- B3GALNT2 | c.792C>A p.F264L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV58355863, COSV58356993; called by muse, varscan2
- B3GALT4 | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV65851241; called by muse, mutect2, varscan2
- B3GALT5 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV58197825; called by muse, mutect2, varscan2
- B3GLCT | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV58453252; called by muse, varscan2
- B3GLCT | c.836T>G p.F279C | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58453265; called by muse, mutect2, varscan2
- B3GNTL1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs769610364, COSV57946783; called by muse, mutect2, varscan2
- B4GALT6 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52702590; called by muse, mutect2, varscan2
- BACH1 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV54517289; called by muse, mutect2, varscan2
- BAG5 | c.754T>G p.L252V | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54570059; called by muse, mutect2, varscan2
- BAG6 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.25); catalogued as rs1375012237, COSV52987861; called by muse, mutect2, varscan2
- BANK1 | c.1763A>G p.Y588C | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536018; called by muse, mutect2
- BATF3 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751958780, COSV54657592; called by muse, mutect2, varscan2
- BAZ2A | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761025019, COSV51631422; called by muse, mutect2, varscan2
- BAZ2B | c.5719C>T p.R1907C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370717896; called by muse, mutect2, varscan2
- BBOF1 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV67454429; called by muse, mutect2, varscan2
- BBS5 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 140/415 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54751728; called by muse, mutect2, varscan2
- BBS9 | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV54156273; called by muse, mutect2, varscan2
- BBX | c.2390T>C p.V797A (on ENST00000325805 / NM_001142568.3; = p.V767A on NM_020235.7) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57878581; called by muse, mutect2, varscan2
- BCAN | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100228019, COSV61255373; called by muse, varscan2
- BCAR3 | c.2043G>T p.E681D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV53071797; called by muse, mutect2, varscan2
- BCAS2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV65767174; called by muse, varscan2
- BCAS3 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV101175527; called by muse, mutect2
- BCAS3 | c.1220A>C p.K407T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66769941; called by muse, varscan2
- BCAS3 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV66769945; called by muse, mutect2, varscan2
- BCAS3 | c.2714T>G p.F905C (on ENST00000390652 / NM_001353144.2; = p.F890C on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV66769948; called by muse, mutect2, varscan2
- BCHE | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52253465, COSV52254588; called by muse, mutect2, varscan2
- BCHE | c.1124G>T p.R375I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1452013632, COSV52253475; called by muse, mutect2, varscan2
- BCL2L1 | c.524A>C p.N175T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV56966278; called by muse, mutect2, varscan2
- BCL2L14 | c.647T>G p.L216R | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53783147; called by muse, mutect2, varscan2
- BCL2L15 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as COSV63642819; called by muse, mutect2, varscan2
- BCLAF3 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs779752496, COSV61413022; called by muse, mutect2, varscan2
- BCOR | c.3812C>T p.S1271L (on ENST00000378444 / NM_001123385.2; = p.S1237L on NM_017745.6) | Missense Mutation (SNP) | VAF 91/309 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs892857458, COSV60699397, COSV60715837; called by muse, mutect2, varscan2
- BCOR | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60698563, COSV60699440; called by muse, mutect2, varscan2
- BDH2 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as COSV56477745; called by muse, mutect2, varscan2
- BDKRB2 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60013547; called by muse, mutect2, varscan2
- BDNF | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 100/307 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1349681470, COSV59233092, COSV59234846; called by muse, varscan2*
- BDNF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs779034534, COSV59233109; called by muse, varscan2
- BDP1 | c.2321C>A p.S774Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV62428800; called by muse, mutect2, varscan2
- BDP1 | c.3185C>T p.T1062M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs763504031, COSV62428805; called by muse, mutect2, varscan2
- BECN1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1302854122, COSV59311627; called by muse, mutect2, varscan2
- BEND2 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs753955004, COSV66215001; called by muse, mutect2, varscan2
- BEND2 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 88/295 reads (30%) | catalogued as COSV66215008; called by muse, mutect2, varscan2
- BFSP1 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV64899300; called by muse, mutect2, varscan2
- BFSP2 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV56586257; called by muse, mutect2, varscan2
- BHMT | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV57153540; called by muse, mutect2, varscan2
- BHMT2 | c.380G>T p.R127I | Missense Mutation (SNP) | VAF 63/106 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV54871756; called by muse, mutect2, varscan2
- BICD1 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV55674629; called by muse, mutect2, varscan2
- BICD1 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 71/226 reads (31%) | catalogued as COSV55674650; called by muse, mutect2, varscan2
- BICDL1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV66906928; called by muse, mutect2, varscan2
- BIRC2 | c.1005C>A p.F335L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV57160579; called by muse, mutect2, varscan2
- BIRC6 | c.3455A>G p.D1152G | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.279); catalogued as COSV70195449; called by muse, varscan2
- BIRC6 | c.10258T>G p.F3420V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV70195453, COSV70207099; called by muse, mutect2, varscan2
- BIRC6 | c.13133G>A p.R4378Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs146403054; called by muse, mutect2, varscan2
- BIRC6 | c.14194C>T p.R4732* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV70195462; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3623A>T p.K1208I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV63243851; called by muse, mutect2, varscan2
- BLK | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs147632595; called by muse, mutect2, varscan2
- BLM | c.3580A>C p.N1194H | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100757059; called by muse, mutect2
- BLOC1S5 | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV55240703; called by muse, mutect2, varscan2
- BLZF1 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV61392700; called by muse, mutect2, varscan2
- BMP1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767291949, COSV60476215; called by muse, mutect2, varscan2
- BMP1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs199971581, COSV60476232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP10 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV54893945; called by muse, mutect2, varscan2
- BMP10 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.328); catalogued as rs777986452, COSV54893960; called by mutect2, varscan2
- BMP2 | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV66576928; called by muse, mutect2, varscan2
- BMP4 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1225275541, COSV55415115; called by muse, mutect2, varscan2
- BMP5 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63700843, COSV63703329; called by muse, mutect2, varscan2
- BMP6 | c.1445A>C p.K482T | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51660461; called by muse, mutect2, varscan2
- BMP7 | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67779502; called by muse, mutect2, varscan2
- BMP8A | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV59031999; called by mutect2, varscan2
- BMS1 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65732839; called by mutect2, varscan2
- BMS1 | c.2641C>T p.R881* | Nonsense Mutation (SNP) | VAF 63/223 reads (28%) | catalogued as rs1457713813, COSV65732842; called by muse, mutect2, varscan2
- BMX | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV59590137; called by muse, mutect2, varscan2
8,645 further variants in this file (6,880 protein-altering or splice-affecting, 1,586 silent, 179 other) are not listed here.
